Surgical pathology report (de-identified scan), TCGA case TCGA-4G-AAZF, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Sapienza University of Rome, specimen TCGA-4G-AAZF-01A (Primary Tumor).

pathology report

Date of tumor procurement:

Anatomic site: intrahepatic

Histology diagnosis: moderately differentiated intrahepatic cholangiocarcinoma

Immunohistochemistry: CK7 positive, CK20 and TTF1 negative

Histological examination:

Liver left: resected parenchyma of 18x11x7 cm containing a grayish-white nodule of 12 cm, located 0.5 cm distant from the resection margin and the retractile capsular. Histologically it is a moderately differentiated adenocarcinoma with an immunohistochemical profile consistent with intrahepatic cholangiocarcinoma with positivity for cytokeratin 7 and negative for cytokeratin 20 and TTF1. The liver tissue shows mild steatosis (5-10%) associated with chronic cholestasis and fibrosis of mild to moderate (grade 2-3/6 fibrosis, Ishak)

ICD-O-3
Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct C22.1
9/24/22/14

Source: NCI Genomic Data Commons file 5899e265-dbc3-4f09-a23f-66f87e15ad1f (TCGA-4G-AAZF.D67904F4-8D02-4D23-9390-C864A7B5344D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).